Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JJ, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JJ-01A (Primary Tumor).

[page 1 of 2]
Requesting Doctor's Information:

ICD-O-3

Carcinoma, adrenal cortical 8370/3
Site: Adrenal Gland, cortex C74.2

QID 1/30/13

SPECIMEN TYPE: Adrenal

CLINICAL NOTES:
Left adrenal cancer.

MACROSCOPIC:

'Tumour left adrenal and left kidney'. The specimen consists of the left kidney, the left adrenal gland and the perinephric fat, 160 x 125 x 70mm, weighing 653g together. The ureter is 35mm in length and 5mm in maximum external diameter. The external surface of the kidney has a nodular appearance with multiple tumour nodules/lymph nodes present in the hilum. There is an area of capsular defect in the posterosuperior aspect of the specimen, 15 x 10mm (? site of tumour sampling for ancillary studies). The cut surface of the specimen shows an enlarged adrenal gland replaced almost entirely by a tan tumour with a heterogenous cut surface showing areas of haemorrhage and large areas of necrosis. This tumour measures 95 x 95 x 70mm and has a multilobulated appearance. Tumour deposits are also identified in the renal vein, as well as six tumour deposits/involved lymph nodes present in the hilum, ranging from 7-40mm in maximum dimension. The kidney, ureter and renal sinuses are not involved by the tumour. The remainder of the kidney is unremarkable. Block 1: transverse section of ureteric margin and hilar vessels. Blocks 2 and 3: tumour deposits in renal vein. Blocks 4 to 11: tumour and overlying capsule, including area of capsular defect noted superior posteriorly in blocks 7 to 10. Block 12: tumour and necrosis. Block 13: tumour and area of haemorrhage. Block 14: tumour interface with kidney. Block 15: kidney away from tumour. Blocks 16 to 20: representative from involved hilar lymph node/tumour deposits; one node in each block, except for block 20, which has two nodes.

MICROSCOPIC:

The 95mm tumour with an estimated weight of 450mg is a poorly differentiated adrenal cortical carcinoma. It shows all 9 of 9 Weiss criteria of malignancy. The mitotic count is 10 mitoses per 10 high power field. There is widespread vascular and sinusoidal invasion. There is extensive coagulative necrosis. The carcinoma is separated from the soft tissue resection margin by an intact, but thin, soft tissue plane 0.2mm. The tumour does not extend into the adjacent kidney, and the adjacent kidney is normal. Carcinoma does invade the renal vein. Metastatic adrenal cortical carcinoma replaces 6 of 6 perirenal lymph nodes. The venous resection margin and ureteric resection margins are free of tumour.

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O

[page 2 of 2]
Requesting Doctor's Information:

SPECIMEN TYPE: Adrenal

Immunohistochemistry is as follows:

IGF2: Positive (dot-like perinuclear pattern)

Glucocorticoid Receptor: 2+ positive

ACADVL: Positive

Ki-67 Proliferative index: 40%

Calretinin, Inhibin: Focally positive

Melan A: Very focally positive

S-100: Negative

SUMMARY:

Left kidney and adrenal: High grade adrenal cortical carcinoma 95mm.

Metastatic carcinoma is present in 6 of 6 lymph nodes.

ADDITIONAL REPORT

At the request of immunohistochemistry for microsatellite instability associated markers was performed. The results are as follows:

MLH1: Positive

MSH2: Positive

PMS2: Positive

MSH6: Positive

Although we have no experience in using this test in adrenal carcinoma, this is the normal pattern of staining which makes Lynch syndrome unlikely.

REPORTING PATHOLOGIST:

(Electronic Signature)

Diagnostic Discrepancy		
H/AA Discrepancy		

Page 2 of 2

Where 'Collected' indicates Rec:

No collection details given: Received details entered as collection details

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

Source: NCI Genomic Data Commons file 6832f04f-0367-48c4-923c-bbf88320e271 (TCGA-OR-A5JJ.AF7A85AB-4C73-40B8-B913-9E540FEDE0FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).